TCGA case TCGA-X6-A8C4 — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: University of Iowa. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b2ee912a-0a57-4d46-bc25-3594028fe387

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 70 years; Vital status: Dead; Days to death: 628 days (1.7 years).

Diagnoses (5)
1. Undifferentiated sarcoma (the primary disease): ICD-O-3 morphology code: 8805/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 70.9 years (25,896 days); Year of diagnosis: 2013; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Tumor burden: 21.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 7.9; Tumor length measurement: 14.7; Tumor width measurement: 9.8.
   Pathology details: Measurement type: Radiologic; Tumor burden: 14.7.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis present: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 6.5; Tumor length measurement: 21; Tumor width measurement: 15.
2. Metastasis of diagnosis 1 (Undifferentiated sarcoma), site: Lung, NOS. Age at diagnosis: 71.1 years (25,967 days); Days to diagnosis: 71 days; Prior treatment: Yes.
   Pathology details: Additional pathology findings: Well Differentiated.
3. Recurrence of diagnosis 1 (Undifferentiated sarcoma), site: Lower limb, NOS. Age at diagnosis: 71.2 years (25,988 days); Days to diagnosis: 92 days; Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 5; Tumor length measurement: 14; Tumor width measurement: 6.
   Pathology details: Additional pathology findings: Well Differentiated.
   Pathology details: Measurement type: Pathologic; Tumor burden: 14.
4. Metastasis of diagnosis 1 (Undifferentiated sarcoma), site: Lung, NOS. Age at diagnosis: 71.8 years (26,213 days); Days to diagnosis: 317 days; Prior treatment: Yes; Tumor focality: Unifocal.
5. Metastasis of diagnosis 1 (Undifferentiated sarcoma), site: Lung, NOS. Age at diagnosis: 72.3 years (26,400 days); Days to diagnosis: 504 days (1.4 years); Prior treatment: Yes; Tumor focality: Unifocal.

Follow-up (8 entries)
- Day 0 (initial diagnosis): Discontiguous lesion count: 1.
- Day 71 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 71 days.
- Day 92 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lower limb, NOS; Days to recurrence: 92 days; Discontiguous lesion count: 1.
- Days to follow up: 268 days; Disease response: With Tumor.
- Day 317 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 317 days.
- Day 504 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 504 days (1.4 years).
- Days to follow up: 512 days (1.4 years); Disease response: With Tumor.
- Days to follow up: 628 days (1.7 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-X6-A8C4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 280 mg.
  Slide TCGA-X6-A8C4-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-X6-A8C4-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-X6-A8C4-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Undifferentiated Pleomorphic Sarcoma (UPS); Margin status: Positive; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Disease multifocal indicator: No; Discontinuous lesions count: 1; Locoregional recurrence indicator: No; Metastatic disease confirmed: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Lower leg/calf.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.
- Drug treatment 1: Treatment on clinical trial: Yes; Days from index date to pharmaceutical treatment started: 156; Clinical trial drug classification: TH-302; Pharmaceutical treatment ongoing indicator: Yes.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Targeted Molecular therapy.
- Drug treatment 2: Treatment on clinical trial: Yes; Days from index date to pharmaceutical treatment started: 327; Pharmaceutical therapy drug name: Doxetaxel; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 2, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 3: Treatment on clinical trial: Yes; Days from index date to pharmaceutical treatment started: 511; Pharmaceutical therapy drug name: Trabectedin; Pharmaceutical treatment ongoing indicator: Yes.
- Drug treatment 4: Treatment on clinical trial: Yes; Days from index date to pharmaceutical treatment started: 327; Pharmaceutical therapy drug name: Bevacizumab; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 5: Treatment on clinical trial: Yes; Days from index date to pharmaceutical treatment started: 327; Pharmaceutical therapy drug name: Gemcitabine; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 6: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 327; Pharmaceutical therapy drug name: Valproic Acid; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Days from index date to radiation therapy started: 44; Days from index date to radiation therapy ended: 78; Radiation therapy type: External; Radiation total dose: 5000; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 25; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 628 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 628 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 71 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-X6-A8C4-01A-11D-A36I-01): tumor purity 0.92, ploidy 3.03, whole-genome doublings 1.
